Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9E5, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9E5-01A (Primary Tumor).

Date of surgery :

Right eye enucleation

Macroscopy

The eye ball measures 23 by 23 by 23 mm with a posterior segment of optic nerve of 10 mm .At the section, the tumor measures 14 mm main line. Samples have been made for cryo preservation, cytogenetic studies and for the preclinical investigation laboratory. The specimen has been then included entirely.

Microscopy

The tumor seen macroscopically corresponds to a choroidal melanoma entirely made of fusiform cells. Tumor cells are tangled in short bundles. Some of them contain melanin pigment. Nuclei of the tumor cells are fusiform, ovoid with sometimes marked anisocaryosis. The mitotic index is low with 4 mitosis out of 10 high 400 magnification fields. The tumor is developed close to the ciliary processes (slide C) and infiltrates the very superficial internal layers of the sclera. The optic foramen, the optic nerve and its cut end are free of tumor. The meningeal sheaths as well as the anterior chamber are free.

Conclusion

Choroidal melanoma of the right eye

Fusiform cell type predominant

Size of the tumor: 14 mm

Infiltration of the internal superficial layers of the sclera

Optic nerve free of the tumor on all its length, including the posterior end

Anterior chamber and meningeal sheaths free

7 Melanoma NOS 8720/3
Site (R) Choroid C69.3
3/10/14

Criteria	10/11/8/13	Yes	No
Staging Discrepancy			
Prognostic Discrepancy			
Case # (Index)	8720/3	DISQUALIFIED	
Review Date	11/1/2013		

Source: NCI Genomic Data Commons file b9a2fae4-0752-40b5-9740-d94a4324ee0d (TCGA-V4-A9E5.8EBDD431-36DB-4197-B4BA-A6F212CAC1C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).